Gene-level copy-number profile of tumor specimen TCGA-G4-6317-02A from TCGA case TCGA-G4-6317, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 51.5 years (18,822 days).
Specimen TCGA-G4-6317-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.283bcb0f-643f-40af-b879-2d5bfc7db4e6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6317-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 354 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e8cf95b-778a-4c81-b69f-6196a4af43d3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 523; copy number 1: 215; copy number 2: 9,424; copy number 3: 22,321; copy number 4: 18,864; copy number 5: 4,736; copy number 6: 242; copy number 7: 731; copy number 8: 1,816; copy number 9: 811; copy number 10: 582; copy number 18: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6317-02A-11D-2062-01): tumor purity 0.86, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr17:18,450,244–18,475,920, 2 genes (within-gene range 0–3): KRT16P4, TNPO1P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,944 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,589,848, 4 genes, copy number 18: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr7:70,972–63,011,569, 1,080 genes, copy number 7–8 (broad region; genes not listed).
- chr7:75,507,747–75,986,855, 11 genes, copy number 7 (within-gene range 4–7): PMS2P3, HIP1, AC004491.1, CCL26, CCL24, AC005102.1, RHBDD2, POR, MIR4651, RPL7L1P3, SNORA14A.
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 9–10 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 215. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
